Surgical pathology report (de-identified scan), TCGA case TCGA-HC-7230, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site International Genomics Consortium, specimen TCGA-HC-7230-01A (Primary Tumor).

Collected:

Received:

Reported:

SPECIMEN

Acct / R

SURGICAL PATHOLOGY REPORT

DIAGNOSIS

DIAGNOSIS:

Radical prostatectomy, bilateral lymph nodes:
Carcinoma.

Tumor Characteristics:

1. Histologic type: Adenocarcinoma, conventional type.
2. Prostate size: 36 grams, 4.7 x 2.9 x 2.4 cm.
3. Tumor quantitation: Approximately 5% of gland volume.
4. Gleason grade:
- a. Primary pattern: 3/5.
- b. Secondary pattern: 4/5.
- c. Total Gleason score: 7/10.
5. Extraprostatic extension: Not identified.
6. Seminal vesicle involvement: Not identified.
7. Lymphovascular space invasion: Not identified.
8. High grade PIN: Present.
9. Treatment effect: Not identified.

Surgical Margin Status:

1. Margins uninvolved.

Lymph Node Status:

1. Total number of lymph nodes received: 3.
2. Total number of lymph nodes containing metastatic carcinoma: None (0/3).

Other:

1. Other significant findings: None.
2. pTNM stage: pT2c N0.

Electronic Signature:

CLINICAL INFORMATION

CLINICAL HISTORY:

Preoperative Diagnosis: with prostate cancer.

Postoperative Diagnosis:

Symptoms/Radiologic Findings:

SPECIMENS:

A. Prostate, VD, SVM bilateral lymph nodes.

SPECIMEN DATA

GROSS DESCRIPTION:

Received labeled and #1 prostate SV Vas deferens and bilateral lymph nodes is a 36 gram prostatectomy specimen consisting of a 4.7 x 2.9 x 2.4 cm prostate, a 3.1 x 0.9 x 0.6 cm left seminal vesicle, a 1.8 x 1.0 x 0.5 cm right seminal vesicle, a 2.7 by 0.3 cm left vas deferens and a 1.9 by 0.3 cm right vas deferens. The orientation of the specimen is not completely obvious. The outer surface of the prostate is shaggy and tan-pink. The cut surface consists of nodular gray-white to tan-yellow soft tissue. Also received in the same container are three irregular to tubular tan-white soft tissues ranging from 0.5 by 0.2 cm to 3.3 by 0.2 cm.

There is also a 4.5 x 2.8 x 0.9 cm aggregate of fibroadipose tissue barring three irregular tan-yellow firm tissues consistent with probable lymph node ranging from 0.6 x 0.4 x 0.2 cm to 3.5 x 2.3 x 0.7 cm.

The specimen is serially sectioned and representative sections are submitted as labeled: 1 -- left apical margin (perpendicular); 2 -- right apical margin (perpendicular); 3 -- left base margin (perpendicular); 4 -- right base margin (perpendicular); 5 -- left posterior apex; 6 -- right posterior apex; 7 -- left anterior apex; 8 -- right anterior apex; 9 -- left posterior mid; 10 -- right posterior mid; 11 -- left anterior mid; 12 -- right anterior mid; 13 -- left posterior base; 14 -- right posterior base; 15 -- left anterior base; 16 -- right anterior base; 17 -- vas deferens margin; left seminal vesicle junction prostate; 18 --

right vas deferens margin and right seminal vesicle junction prostate; 19 -- end of larger tubular tissue; 20 -- smaller tubular tissue bisected and entirely submitted; 21 -- additional irregular tissue, bisected and entirely submitted; 22 -- one whole probable lymph node; 23 -- one lymph node bisected; 24 and 25 -- one lymph node bisected. The blocks are labeled
Also received in the same container is a blue-yellow and green cassette
labeled for

Source: NCI Genomic Data Commons file e742fe55-150f-4da7-b4c1-7443daa248c0 (TCGA-HC-7230.0C078733-C8ED-4D5C-9DA0-979F4AF4FC4F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).